Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7740, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7740-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

DIAGNOSIS:

- A. Bilateral pelvic lymph nodes; excision:
No metastatic carcinoma identified in four lymph nodes (0/4).
- B. Prostate; radical prostatectomy:
- Tumor Characteristics:**
1. Histologic type: Prostate adenocarcinoma.
2. Prostate size: 4.5 x 4.0 x 4.0, 35 grams.
3. Tumor quantitation: Tumor involves less than 5% of the prostate gland volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Present.
9. Treatment effect: Not identified.
- Surgical Margin Status:**
1. The tumor focally abuts the left anterior inked capsule.
2. Apical and bladder neck margins negative for tumor.
- Lymph Node Status:**
1. Total number of lymph nodes received: 4, see specimen A.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/4).
- Other:**
1. pTNM stage: pT2c N0.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Bilateral pelvic lymph nodes
B. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patient's name

A. Additionally labeled #1 and contains a 5.0 x 4.3 x 2.4 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation, four ill defined firm fatty possible lymph nodes are identified ranging from 1.2 up to 4.5 cm in greatest dimension. They are entirely submitted in cassettes A1-8 labeled designated as follows: A1—one whole possible lymph node; A2—one whole possible bisected lymph node; A3 and 4—one whole possible bisected lymph node; A5-8—one whole possible quadrisectioned lymph node.

B. Additionally labeled #2 and contains a 34.6 gram, 4.5 x 4.0 x 4.0 cm prostate received with attached bilateral adnexa having overall dimensions of 4.0 x 3.0 x 1.0 cm. The capsule is pink-tan and shaggy. The specimen is inked as follows: right side - blue and left side - black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal pink-tan focally cystic, fibrous cut surface

[page 2 of 2]
with no discrete lesions. Representative sections are submitted in cassettes B1-18 labeled _____ designated as follows: 1--right prostate/seminal vesicle junction; 2--left prostate/seminal vesicle junction; 3-4--apical margin, perpendicular; 5-6--base margin, perpendicular; 7-9--right anterior, apex to base; 10-12--right posterior, apex to base; 13-15--left anterior, apex to base; 16-18--left posterior, apex to base. Additionally, a yellow and green cassette are submitted for Genomics research each labeled _____

Source: NCI Genomic Data Commons file 5a8bdb52-0591-4046-a7dc-f53c828205bb (TCGA-HC-7740.D2B80346-3A50-4FC3-99C2-0E15225CC433.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).